Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A66B, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A66B-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Surgicals

Surgical Pathology Consultation / Department of Pathology

ICD-O-3
path Astrocytoma, gemistocytic 9411/3
CHF Astrocytoma, anaplastic 9401/3
Site path Brain NOS C71.9
CHF Brain, supratentorial NOS
C71.0
W 5/10/13

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

- | | |
|---------------------|---------------------------------|
| A. Left brain tumor | A. Frozen Section Charge |
| B. Left brain tumor | B. Glial Fibrill. Acid Prt |
| B. P53 Protein | B. KI-67, Nuclear Antigen, Mib1 |
| C. Left brain tumor | |

CLINICAL HISTORY: year old male with history of a newly diagnosed left temporal brain tumor.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name

- A. Left brain tumor
- B. Left brain tumor
- C. Left brain tumor

- A. The specimen is received fresh for frozen section, designated "Left brain tumor" and consists of a roughly wedge shaped piece of rubbery, pink-tan soft tissue that is 1.5 x 1.4 x 0.6 cm. A touch prep is made and a representative piece is submitted for frozen section. Frozen section diagnosis is "Astrocytoma with gemistocytic features," per Dr. [redacted]. Frozen tissue is resubmitted for permanents in cassette FSA1 and remaining tissue is submitted in cassette A2. (
- B. The specimen is received fresh, designated "Left brain tumor" and consists of multiple pieces of slightly firm, rubbery, pink-tan soft tissue measuring 3.0 x 2.3 x 0.6 cm in aggregate. A representative portion is submitted to the tumor bank. Cut surfaces are homogenous, glistening and pale tan. Representative sections are submitted in cassettes B1 and B2. [redacted]
- C. The specimen is received fresh, designated "Left brain tumor" and consists of a 5.7 x 4.2 x 0.9 cm aggregate of somewhat gelatinous, red-tan soft tissue. The specimen is markedly soft and somewhat friable on sectioning. Cut surfaces are glistening, homogenous pale-tan. Representative sections are submitted in cassettes C1 through C5. [redacted]

DIAGNOSIS:

- A. "Left brain tumor, resection":
Anaplastic astrocytoma (WHO Grade III) (see comment)
- B. "Left brain tumor, resection":
Anaplastic astrocytoma (WHO Grade III) (see comment)
- C. "Left brain tumor, resection":
Anaplastic astrocytoma (WHO Grade III) (see comment)

COMMENT: Sections show a diffusely infiltrating astrocytoma with prominent gemistocytic phenotype, nuclear pleomorphism and hyperchromasia

[page 2 of 3]
and increased mitoses. Numerous microcysts are seen in the background. There are occasional apoptotic tumor cells but definitive tumor necrosis is not identified in this material. In addition, hyperplastic blood vessels with fibrin thrombi are seen but definitive vascular endothelial proliferation is not readily identified in this material. There is a prominent perivascular infiltrate of mature lymphocytes.

Immunohistochemical stains show that the majority of tumor cells are immunoreactive for GFAP. P53 immunostain shows rare individual weakly immunoreactive tumor cells. Ki-67 shows an elevated proliferation index of up to 10% approximately. These findings support the diagnosis. There is a subpopulation of tumor cells with rounded nuclei and perinuclear halos but with prominent nuclear pleomorphism. Analysis of 1p19q chromosomal status will be performed and results reported in an addendum. Correlation with clinical and imaging findings is strongly recommended. Dr. [REDACTED] has reviewed this case and concurs.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

[REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Pathologist

ADDENDUM:

CHROMOSOMES 1P AND 19Q ANALYSIS:

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) WAS PERFORMED ON REPRESENTATIVE PARAFFIN-EMBEDDED TUMOR TISSUE

IN THIS CASE, NO DELETIONS OF 1P OR 19Q WERE IDENTIFIED.

REFERENCES:

1. CAIRNCROSS JG, UEKI K, ZLATESCU MC ET AL. SPECIFIC GENETIC PREDICTORS OF CHEMOTHERAPEUTIC RESPONSE AND SURVIVAL IN PATIENTS WITH ANAPLASTIC OLIGODENDROGLIOMAS. J NATL CANCER INST 90:1473-1479, 1998.
2. SMITH JS, PERRY A, BORELL TJ, ET AL. ALTERATIONS OF CHROMOSOME ARMS 1P AND 19Q AS PREDICTORS OF SURVIVAL IN OLIGODENDROGLIOMAS, ASTROCYTOMAS, AND MIXED OLIGOASTROCYTOMAS. J CLIN ONCOL 18:636-45, 2000.
3. PERRY A, FULLER CE, BANERJEE R, BRAT DJ, SCHEITHAUER BW. ANCILLARY FISH ANALYSIS FOR 1P AND 19Q STATUS: PRELIMINARY OBSERVATIONS IN 287 GLIOMAS AND OLIGODENDROGLIOMA MIMICS. FRONT BIOSCI 8:A1-9, 2003.
4. MCDONALD JM, SEE SJ, TREMONT IW, ET AL. THE PROGNOSTIC IMPACT OF HISTOLOGY AND 1P/19Q STATUS IN ANAPLASTIC OLIGODENDROGLIAL TUMORS. CANCER. 104:1468-77, 2005
5. CAIRNCROSS G, BERKEY B, SHAW E, JENKINS R, SCHEITHAUER B, BRACHMAN D, BUCKNER J, FINK K, SOUHAMI L, LAPERRIERE N, MEHTA M, CURRAN W. PHASE III TRIAL OF CHEMOTHERAPY PLUS RADIOTHERAPY COMPARED WITH RADIOTHERAPY ALONE FOR PURE AND MIXED ANAPLASTIC OLIGODENDROGLIOMA: INTERGROUP RADIATION THERAPY ONCOLOGY GROUP TRIAL 9402.

<<http://www.ncbi.nlm.nih.gov/pubmed/16782910?ordinalpos=23&itool=EntrezSy> stem2.PEntrez.Pubmed.PubmedbResultsPanel.PubmedbDefaultReportPanel.Pubmed

[page 3 of 3]
bRVDocSum> J CLIN ONCOL. 2006 JUN 20;24(18):2707-14.

Pathologist

Source: NCI Genomic Data Commons file a84c0444-222e-4a13-9566-b24852eafe22 (TCGA-DH-A66B.7D6D3FE4-FA4C-4827-B141-9E323AC6B1A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).